Somatic mutation profile of tumor specimen TCGA-EV-5902-01A (aliquot TCGA-EV-5902-01A-11D-1589-08) from TCGA case TCGA-EV-5902, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 58.4 years (21,344 days).
Specimen TCGA-EV-5902-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef26eff2-39a9-40e5-99f8-232693dc2496.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EV-5902-10A (Blood Derived Normal), aliquot TCGA-EV-5902-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58f5385f-3937-4a21-a808-3a5550663ef2

The open-access MAF lists 90 somatic variants for this specimen: 70 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, Frame Shift Del 10, Frame Shift Ins 5, Nonsense Mutation 2, Intron 2, Splice Site 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM1 | c.1337T>C p.M446T | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53315494; called by muse, mutect2, varscan2
- AC131160.1 | c.961G>C p.A321P | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV57702251; called by muse, mutect2, varscan2
- ACSL6 | c.565A>T p.I189F (on ENST00000379240; = p.I214F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746439546, COSV57304793; called by muse, varscan2
- AHDC1 | c.2680A>C p.K894Q | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55942278; called by muse, mutect2, varscan2
- AMBP | c.281del p.T94Sfs*23 | Frame Shift Del (DEL) | VAF 41/106 reads (39%) | catalogued as COSV99468781; called by mutect2, pindel, varscan2
- ANXA3 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762300727, COSV53717312; called by muse, mutect2, varscan2
- APPBP2 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50029309; called by muse, mutect2, varscan2
- ATP10B | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV58781249; called by muse, mutect2, varscan2
- ATP10B | c.294C>G p.F98L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58778943, COSV58781253; called by muse, mutect2, varscan2
- BCL2L13 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs747751039, COSV58227488, COSV58227580; called by muse, mutect2, varscan2
- BIRC6 | c.4088A>C p.H1363P | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV70205568; called by muse, mutect2, varscan2
- BTNL8 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 452/699 reads (65%) | SIFT tolerated (0.39); PolyPhen benign (0.367); catalogued as rs371555886; called by muse, mutect2, varscan2
- CACNA1A | c.3179G>A p.R1060H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs200850308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV58116124; called by muse, mutect2
- CNDP2 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV60841598; called by muse, mutect2, varscan2
- CNTN3 | c.1872C>A p.N624K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55183789; called by muse, mutect2, varscan2
- COCH | c.1630T>C p.Y544H (on ENST00000216361 / NM_001347720.1; = p.Y479H on NM_004086.3) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53552976; called by muse, mutect2, varscan2
- ELMO3 | c.1451T>G p.M484R (on ENST00000652269; = p.M431R on NM_024712.5) | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV58528345; called by muse, mutect2
- ENAM | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.612); catalogued as COSV68536980; called by muse, mutect2, varscan2
- FERMT2 | c.485A>G p.E162G | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.174); catalogued as COSV58409325; called by muse, mutect2, varscan2
- FLG | c.7690G>T p.G2564* | Nonsense Mutation (SNP) | VAF 208/403 reads (52%) | catalogued as COSV64242509, COSV64248608; called by muse, mutect2, varscan2
- GBA2 | c.1784T>C p.I595T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs1035304750, COSV62306771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPLL | c.1598A>T p.K533M | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55369267; called by muse, mutect2, varscan2
- IGHG2 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs1273133495; called by muse, mutect2
- IL1RL2 | c.875A>C p.E292A | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV51818782; called by muse, mutect2, varscan2
- LRRN3 | c.952A>G p.N318D | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57823898; called by muse, mutect2, varscan2
- LZTFL1 | c.451A>C p.N151H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56112494; called by muse, mutect2, varscan2
- METTL25 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs768610536, COSV50261957; called by muse, mutect2, varscan2
- MRPS5 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55535373; called by muse, mutect2, varscan2
- MRTFB | c.2273C>G p.T758S (on ENST00000571589 / NM_001365412.2; = p.T708S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as rs1332833290, COSV57961540; called by muse, mutect2, varscan2
- MTCH1 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV65321437; called by muse, mutect2, varscan2
- MTRR | c.268G>A p.G90R (on ENST00000264668; = p.G63R on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759310852, COSV52946735; called by muse, mutect2, varscan2
- MYCBP2 | c.2659A>G p.K887E (on ENST00000357337; = p.K925E on NM_015057.5) | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62038380; called by muse, mutect2, varscan2
- MYO1F | c.1426G>T p.D476Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57800049; called by muse, mutect2, varscan2
- NCAM2 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.386); catalogued as COSV53102286; called by muse, mutect2, varscan2
- NR1D2 | c.584T>G p.M195R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56993763; called by muse, mutect2, varscan2
- OR2AT4 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV59407658; called by muse, mutect2, varscan2
- PIK3R1 | c.1784A>T p.N595I (on ENST00000521381 / NM_181523.3; = p.N325I on NM_181504.4) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57139141; called by muse, mutect2, varscan2
- PROSER1 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV61489562; called by muse, mutect2, varscan2
- RICTOR | c.2649T>G p.Y883* | Nonsense Mutation (SNP) | VAF 135/228 reads (59%) | catalogued as COSV57130309; called by muse, mutect2, varscan2
- RPGRIP1L | c.3909G>T p.Q1303H | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV50916838; called by muse, mutect2, varscan2
- SCN11A | c.4415G>A p.R1472Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343553308, COSV56566727; called by muse, mutect2
- SHOC1 | c.971T>A p.F324Y | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV59507052; called by muse, mutect2, varscan2
- SLC3A1 | c.611-1G>C p.X204_splice | Splice Site (SNP) | VAF 30/68 reads (44%) | catalogued as COSV53224835; called by muse, mutect2, varscan2
- TGM4 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147559877; called by muse, mutect2, varscan2
- TNPO3 | c.1538A>T p.K513M | Missense Mutation (SNP) | VAF 75/127 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV55286674; called by muse, mutect2, varscan2
- TRAPPC8 | c.1102A>C p.I368L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as rs1432362778, COSV51977140; called by muse, varscan2
- TRIO | c.5897C>T p.S1966F | Missense Mutation (SNP) | VAF 80/109 reads (73%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60094997; called by muse, mutect2, varscan2
- TUBB4B | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61118934; called by muse, mutect2, varscan2
- WNT10A | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378858796, COSV51461491, COSV51463652; called by muse, mutect2, varscan2
- YTHDC1 | c.458A>C p.E153A | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV60012022; called by muse, mutect2, varscan2
- ZDHHC9 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 75/77 reads (97%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV64097378; called by muse, mutect2, varscan2
- ZNF236 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs1333941371, COSV53495054; called by muse, mutect2, varscan2
- ZNF320 | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67088921; called by muse, mutect2, varscan2
- ZNF780B | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.966); catalogued as COSV55468090; called by muse, mutect2, varscan2
- CASP10 | c.1061_1062del p.C354Yfs*15 (on ENST00000272879 / NM_032974.5; = p.C311Yfs*15 on NM_001230.5) | Frame Shift Del (DEL) | VAF 73/180 reads (41%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.3541_3542dup p.A1182Qfs*17 | Frame Shift Ins (INS) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- DHX57 | c.3857del p.K1286Rfs*2 | Frame Shift Del (DEL) | VAF 67/194 reads (35%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.560_568delinsG p.Q187Rfs*29 | Frame Shift Del (DEL) | VAF 39/170 reads (23%) | called by pindel, varscan2*
- LINS1 | c.1938_1939insT p.S647* | Frame Shift Ins (INS) | VAF 39/133 reads (29%) | called by mutect2, pindel*
- MBIP | c.912dup p.V305Sfs*12 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | called by mutect2, pindel, varscan2
- MRPL22 | c.108del p.S36Rfs*39 | Frame Shift Del (DEL) | VAF 109/201 reads (54%) | called by mutect2, pindel, varscan2
- NF2 | c.1076_1091del p.R359Kfs*11 | Frame Shift Del (DEL) | VAF 33/39 reads (85%) | called by mutect2, pindel, varscan2
- NIPSNAP2 | c.229_230del p.Q77Vfs*5 | Frame Shift Del (DEL) | VAF 65/150 reads (43%) | called by mutect2, pindel, varscan2
- RABGAP1 | c.1479_1483del p.V494Pfs*18 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- RLF | c.5016_5017insT p.K1673* | Frame Shift Ins (INS) | VAF 44/105 reads (42%) | called by mutect2, pindel, varscan2
- SNX10 | c.597_*8del | Nonstop Mutation (DEL) | VAF 72/174 reads (41%) | called by mutect2, pindel
- STMN4 | c.432del p.K144Nfs*40 (on ENST00000265770 / NM_001283054.2; = p.K171Nfs*40 on NM_030795.4) | Frame Shift Del (DEL) | VAF 67/178 reads (38%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.3177dup p.E1060Rfs*7 | Frame Shift Ins (INS) | VAF 21/186 reads (11%) | called by mutect2, pindel
- ZER1 | c.410del p.F137Sfs*49 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- AC131160.1 | c.960A>C p.T320= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV57702257; called by muse, mutect2, varscan2
- CFAP54 | c.7509A>T p.T2503= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV61575105; called by muse, mutect2, varscan2
- CRAMP1 | c.3303C>T p.I1101= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs765590076, COSV51965982; called by muse, mutect2, varscan2
- FSHR | c.1632C>T p.V544= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV58634505; called by muse, mutect2, varscan2
- KIZ | c.687T>A p.S229= | Silent (SNP) | VAF 132/174 reads (76%) | catalogued as COSV55688068; called by muse, mutect2, varscan2
- MAP11 | c.1284C>T p.A428= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV57588222; called by muse, mutect2, varscan2
- MYO7A | c.354C>T p.H118= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs782130934, COSV68686967; called by muse, mutect2, varscan2
- MYOC | c.1239C>G p.L413= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as COSV50674694, COSV50678569; called by muse, mutect2, varscan2
- OBSCN | c.9081G>C p.R3027= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV52826178; called by muse, mutect2, varscan2
- PIK3CB | c.762A>G p.V254= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV56690178; called by muse, mutect2, varscan2
- PIK3R1 | c.1008A>G p.G336= (on ENST00000521381 / NM_181523.3; = p.G66= on NM_181504.4) | Silent (SNP) | VAF 68/209 reads (33%) | catalogued as COSV57139127; called by muse, mutect2, varscan2
- PLEC | c.8607G>A p.A2869= (on ENST00000322810 / NM_201380.4; = p.A2759= on NM_000445.5) | Silent (SNP) | VAF 3/55 reads (5%) | catalogued as rs372807129, COSV59693487; called by muse, mutect2
- RNF168 | c.423C>A p.A141= | Silent (SNP) | VAF 99/203 reads (49%) | catalogued as COSV58839466; called by muse, mutect2, varscan2
- TENM1 | c.5877C>A p.T1959= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV64442358; called by muse, mutect2, varscan2
- TRIM22 | c.48C>T p.P16= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs1185939755, COSV66091776; called by muse, mutect2, varscan2
- USP4 | c.621A>G p.L207= | Silent (SNP) | VAF 90/194 reads (46%) | catalogued as COSV55540423; called by muse, mutect2, varscan2
- ZNF169 | c.1398C>T p.G466= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV61766543; called by muse, mutect2, varscan2
- TPT1 | c.517-203C>A | Intron (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100495992; called by muse, mutect2, varscan2
- TTN | c.34523-159A>C | Intron (SNP) | VAF 88/194 reads (45%) | catalogued as COSV100621717; called by muse, mutect2, varscan2
- XIRP2 | c.*919_*922del | 3'UTR (DEL) | VAF 45/81 reads (56%) | called by mutect2, pindel, varscan2
